Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6BK, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6BK-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:

y/o female with left retroperitoneal mass.

Specimens Submitted:

- 1: SP: Retroperitoneal sarcoma
- 2: SP: Hernia sac

DIAGNOSIS:

1. SOFT TISSUE, RETROPERITONEUM; EXCISION:
- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND IS COMPOSED MAINLY OF A HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA-LIKE PATTERN, BUT FOCALLY SHOWS A LOW GRADE MYXOFIBROSARCOMA-LIKE GROWTH.
- IN ADDITION, AREAS OF WELL-DIFFERENTIATED LIPOSARCOMA, SCLEROSING TYPE, ARE PRESENT.
- TUMOR SIZE: 11.8 x 10.5 x 10.2 CM.
- THE TUMOR IS PRESENT AT THE INKED RESECTION MARGIN.
- FOCI OF NECROSIS ARE PRESENT, BUT THE TUMOR IS PREDOMINANTLY VIABLE.
2. SOFT TISSUE, ABDOMINAL WALL; EXCISION:
- BENIGN FIBROADIPOSE TISSUE, CONSISTENT WITH HERNIA SAC.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh labeled, "retroperitoneal sarcoma", and consists of one irregular, unoriented, round fragment of soft tissue measuring 12.5 x 12.2 x 11.5 cm. The surface of the specimen is pink, tan, smooth and almost entirely covered by a thin glistening membrane. There is an area that appears to be covered by peritoneum, measuring 7.5 x 7 x 6.3 cm. The external surface is inked black. The cut section reveals the

** Continued on next page **

ICD-0-3

Liposarcoma, dedifferentiated
885813
Site Retroperitoneum
248.0
gn 5/21/10

[page 2 of 2]
SURGICAL

----- Page 2 of 2
white/yellow, slightly lobulated firm mass occupying the entire specimen,
measuring 11.8 x 10.5 x 10.2 cm, and abutting the inked surface. The
specimen is photographed. A portion of the tumor is submitted for TPS .

Summary of sections:

PM areas covered by peritoneum
RS representative sections

2). The specimen is received in formalin labeled "hernia sac" and consists
of a 4 x 2.9 x 1.3 cm aggregate of yellow-tan, lobulated to purple-pink,
membranous portion of soft tissue. Sectioning reveals white-pink,
membranous to yellow-tan, lobulated cut surfaces with no gross lesions.
Representative sections are submitted.

Summary of sections:

U -- undesignated

Summary of Sections:

Part 1: SP: Retroperitoneal sarcoma

Block	Sect. Site	PCs
5	PM	5
15	RS	15

Part 2: SP: Hernia sac

Block	Sect. Site	PCs
1	U	2

** End of Report **

Criteria:	hw 5/5/13	Yes	No
Diagnostic Discrepancy			✓
Prior Malignancy History	Breast	✓	✓

Source: NCI Genomic Data Commons file a60270d8-e442-4cf1-b9e8-5a897b3b8a84 (TCGA-DX-A6BK.194F513D-4FD9-40F4-8F8E-EE10D142CDDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).